Somatic mutation profile of tumor specimen TARGET-50-PAJNGH-02A (aliquot TARGET-50-PAJNGH-02A-01D) from TARGET case TARGET-50-PAJNGH, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.3 years (851 days).
Specimen TARGET-50-PAJNGH-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 990076ff-20b2-4978-b5a4-28e22a88f316.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNGH-10A (Blood Derived Normal), aliquot TARGET-50-PAJNGH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20c3794e-e3c7-4a36-9144-26e5136ec991

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.4139C>A p.S1380* | Nonsense Mutation (SNP) | VAF 38/89 reads (43%) | catalogued as COSV62321398; called by muse, mutect2
- ADCY5 | c.2406G>T p.L802F | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.017); catalogued as COSV59198610; called by muse, mutect2, varscan2
- PTPN13 | c.2714G>A p.R905Q | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs189080752; called by muse, mutect2, varscan2
- RNF115 | c.275G>T p.S92I | Missense Mutation (SNP) | VAF 534/1120 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV65164663; called by muse, mutect2, varscan2
- FNTA | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 58/337 reads (17%) | called by muse, mutect2, varscan2
- NFAT5 | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 150/329 reads (46%) | called by muse, mutect2, varscan2
- PCDH12 | c.2219G>T p.C740F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SHROOM2 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by mutect2, varscan2
- TTN | c.68891C>A p.A22964D (on ENST00000591111; = p.A15540D on NM_003319.4) | Missense Mutation (SNP) | VAF 6/147 reads (4%) | PolyPhen possibly damaging (0.81); called by muse, mutect2
- ZSCAN12 | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2
- FGD2 | c.1353G>A p.R451= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
